Somatic mutation profile of tumor specimen 318d53c3-216b-4de1-a098-77d6dd (aliquot 318d53c3-216b-4de1-a098-77d6dd_D6) from CPTAC case 04OV031, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 318d53c3-216b-4de1-a098-77d6dd: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e35bdc55-73f6-403e-92a4-33a5659117fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 3f6e343a-2105-49d1-a38f-a7e2f3 (Blood Derived Normal), aliquot 3f6e343a-2105-49d1-a38f-a7e2f3_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3f94318-2624-4ecb-bfa4-4894e024eb49

The open-access MAF lists 96 somatic variants for this specimen: 66 protein-altering or splice-affecting, 16 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 16, Intron 10, Splice Region 4, Frame Shift Del 4, Splice Site 3, 5'Flank 2, Nonsense Mutation 2, 3'UTR 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF19 | c.1673A>G p.N558S | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs746417210; called by muse, mutect2, varscan2
- ATF6B | c.1318C>G p.L440V | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1179719370; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as COSV99267433; called by muse, mutect2, varscan2
- DRAP1 | c.318G>C p.K106N | Missense Mutation (SNP) | VAF 104/237 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.351); catalogued as rs371036532; called by muse, mutect2, varscan2
- DST | c.21328C>T p.R7110W (on ENST00000361203 / NM_001374722.1; = p.R4807W on NM_015548.5) | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754663787, COSV55010401; called by muse, mutect2, varscan2
- FAM83C | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 80/254 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs754349955, COSV65584478; called by muse, mutect2, varscan2
- IGLV2-18 | c.170A>T p.Y57F | Missense Mutation (SNP) | VAF 168/623 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.109); catalogued as rs1269782419; called by muse, mutect2, varscan2
- LILRA2 | c.557G>C p.S186T | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52197251, COSV99063649; called by muse, mutect2, varscan2
- PILRA | c.882C>G p.N294K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs374643830; called by muse, mutect2, varscan2
- PKHD1 | c.11785+1G>A p.X3929_splice | Splice Site (SNP) | VAF 105/451 reads (23%) | catalogued as COSV64395274; called by muse, mutect2, varscan2
- RB1 | c.931C>G p.L311V | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as CD050469; called by muse, mutect2
- RGS10 | c.378C>A p.I126= (on ENST00000369101; = p.I120= on NM_002925.3) | Splice Region (SNP) | VAF 31/96 reads (32%) | catalogued as COSV64861923; called by muse, mutect2, varscan2
- SORCS3 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs759288838, COSV63830620; called by muse, mutect2
- STYXL2 | c.1763C>G p.A588G | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99608738; called by muse, mutect2, varscan2
- TES | c.593T>C p.M198T | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.017); catalogued as rs771589187, COSV64042669; called by muse, mutect2, varscan2
- TP53 | c.988del p.L330Ffs*15 | Frame Shift Del (DEL) | VAF 66/211 reads (31%) | catalogued as COSV53825922, COSV99461761; called by mutect2, pindel, varscan2
- ZNF565 | c.1141G>A p.G381R (on ENST00000355114; = p.G341R on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs750177810, COSV58410652, COSV58411628; called by muse, mutect2, varscan2
- ACAN | c.4799C>A p.A1600D | Missense Mutation (SNP) | VAF 190/486 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ADCY9 | c.2233C>A p.P745T | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AHNAK | c.12552G>T p.W4184C | Missense Mutation (SNP) | VAF 120/390 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); called by mutect2, varscan2
- AHNAK | c.12551G>A p.W4184* | Nonsense Mutation (SNP) | VAF 124/401 reads (31%) | called by muse, mutect2, varscan2
- ARFGEF2 | c.2056G>T p.E686* | Nonsense Mutation (SNP) | VAF 65/588 reads (11%) | called by muse, mutect2, varscan2
- BMP2K | c.2975_2978del p.S992Mfs*16 | Frame Shift Del (DEL) | VAF 83/334 reads (25%) | called by mutect2, pindel, varscan2
- CAPRIN1 | c.1954A>G p.T652A | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAPZA3 | c.31A>C p.K11Q | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- CIAO1 | c.163G>C p.V55L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- COL19A1 | c.2791G>T p.D931Y | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- COL6A5 | c.7616A>G p.D2539G (on ENST00000312481; = p.D2535G on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRTC2 | c.2055G>C p.E685D | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- DBH | c.1722+6C>T | Splice Region (SNP) | VAF 98/341 reads (29%) | called by muse, mutect2, varscan2
- DENND5B | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.138); called by muse, mutect2
- EPAS1 | c.998A>G p.Q333R | Missense Mutation (SNP) | VAF 141/518 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- F11R | c.696G>A p.V232= | Splice Region (SNP) | VAF 45/186 reads (24%) | called by muse, mutect2, varscan2
- FCGR2B | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 204/667 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALR2 | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 154/398 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GPR160 | c.821A>C p.E274A | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- GUF1 | c.1189G>C p.G397R | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEXA | c.47T>G p.F16C | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- HSPA1L | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 76/377 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- IZUMO3 | c.142A>G p.T48A | Missense Mutation (SNP) | VAF 218/644 reads (34%) | SIFT tolerated (0.55); called by muse, mutect2, varscan2
- KMT2D | c.8581C>A p.L2861M | Missense Mutation (SNP) | VAF 59/276 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- LIPG | c.1139A>G p.Q380R | Missense Mutation (SNP) | VAF 111/580 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- MDGA1 | c.2576C>T p.A859V | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MRPS28 | c.183G>C p.E61D | Missense Mutation (SNP) | VAF 46/344 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NSD3 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- ODF3L2 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PGR | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 59/476 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- PLAA | c.1418-1G>C p.X473_splice | Splice Site (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- PLBD1 | c.10G>T p.G4C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRDM13 | c.1444C>A p.L482I | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2
- ROBO2 | c.3761-4T>A | Splice Region (SNP) | VAF 73/261 reads (28%) | called by muse, mutect2, varscan2
- RTEL1 | c.2463G>C p.E821D | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SFTPC | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 14/450 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); called by muse, mutect2
- SLC16A12 | c.7T>C p.S3P | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNTG2 | c.685A>G p.I229V | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STK11IP | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 95/473 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- STXBP1 | c.1089C>A p.D363E | Missense Mutation (SNP) | VAF 104/360 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- TENT2 | c.839T>G p.L280W | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRAM1L1 | c.1015T>C p.S339P | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TSC2 | c.239_246del p.A80Efs*43 | Frame Shift Del (DEL) | VAF 44/144 reads (31%) | called by mutect2, pindel, varscan2
- TUT7 | c.2371G>T p.G791C | Missense Mutation (SNP) | VAF 108/401 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); called by muse, varscan2
- TUT7 | c.2290_2320del p.T764Sfs*16 | Frame Shift Del (DEL) | VAF 88/430 reads (20%) | called by pindel, varscan2
- UHRF1BP1L | c.2431_2436del p.V811_H812del | In Frame Del (DEL) | VAF 38/238 reads (16%) | called by pindel, varscan2
- UNC5B | c.80-1G>T p.X27_splice | Splice Site (SNP) | VAF 81/281 reads (29%) | called by muse, mutect2, varscan2
- ZNF777 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.579); called by muse, varscan2
- ZNRF3 | c.1811C>A p.P604H (on ENST00000544604 / NM_001206998.2; = p.P504H on NM_032173.3) | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ARHGAP39 | c.2532A>T p.I844= (on ENST00000276826 / NM_001308208.2; = p.I875= on NM_025251.2) | Silent (SNP) | VAF 116/231 reads (50%) | called by muse, mutect2, varscan2
- BRAF | c.2304A>T p.A768= (on ENST00000288602 / NM_001374244.1; = p.A728= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 56/117 reads (48%) | called by muse, mutect2, varscan2
- DOCK8 | c.2532G>A p.R844= | Silent (SNP) | VAF 121/611 reads (20%) | catalogued as rs1234416169, COSV66621915; called by muse, mutect2, varscan2
- EGLN1 | c.426C>G p.A142= | Silent (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- EPHB4 | c.927C>T p.F309= | Silent (SNP) | VAF 20/107 reads (19%) | called by muse, mutect2, varscan2
- FCRLB | c.822C>A p.R274= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2
- GALR2 | c.882G>A p.L294= | Silent (SNP) | VAF 148/382 reads (39%) | catalogued as rs145000591; called by muse, mutect2, varscan2
- GLI2 | c.4296C>G p.G1432= (on ENST00000361492 / NM_001374353.1; = p.G1449= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/212 reads (24%) | called by muse, mutect2, varscan2
- NUDT21 | c.24C>G p.R8= | Silent (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- PCDHA10 | c.297G>A p.V99= | Silent (SNP) | VAF 177/476 reads (37%) | called by muse, mutect2, varscan2
- PI4KA | c.2808G>T p.V936= | Silent (SNP) | VAF 48/252 reads (19%) | called by muse, mutect2, varscan2
- RASL11B | c.45G>T p.A15= | Silent (SNP) | VAF 64/148 reads (43%) | catalogued as rs536266991; called by muse, mutect2, varscan2
- RGPD8 | c.54C>T p.L18= | Silent (SNP) | VAF 41/80 reads (51%) | catalogued as COSV100221782; called by mutect2, varscan2
- SIGLEC8 | c.1389G>A p.Q463= | Silent (SNP) | VAF 50/175 reads (29%) | called by muse, mutect2, varscan2
- TEDC1 | c.678C>A p.G226= | Silent (SNP) | VAF 30/96 reads (31%) | called by muse, mutect2, varscan2
- TTPAL | c.198G>T p.R66= | Silent (SNP) | VAF 72/431 reads (17%) | called by muse, mutect2, varscan2
- AGER | c.691+44C>T | Intron (SNP) | VAF 16/150 reads (11%) | called by muse, mutect2
- AP000769.5 | chr11:65498508 C>A | 5'Flank (SNP) | VAF 8/212 reads (4%) | called by muse, mutect2
- ASPH | c.254-1422C>G | Intron (SNP) | VAF 45/268 reads (17%) | called by muse, mutect2, varscan2
- CLPSL2 | c.207+319C>A | Intron (SNP) | VAF 37/140 reads (26%) | called by muse, mutect2, varscan2
- DENND3 | c.956+2168G>T | Intron (SNP) | VAF 23/90 reads (26%) | called by muse, mutect2, varscan2
- DHCR24 | c.387+37G>T | Intron (SNP) | VAF 84/324 reads (26%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+7738G>T | Intron (SNP) | VAF 108/416 reads (26%) | catalogued as rs920599736; called by muse, mutect2, varscan2
- MUCL3 | c.946+1297C>A | Intron (SNP) | VAF 52/279 reads (19%) | called by muse, mutect2, varscan2
- NDUFA10 | c.1000-12405C>G | Intron (SNP) | VAF 31/130 reads (24%) | called by muse, mutect2, varscan2
- NXF5 | n.481T>A | RNA (SNP) | VAF 81/239 reads (34%) | called by muse, mutect2, varscan2
- RGMA | c.15-706G>C | Intron (SNP) | VAF 58/166 reads (35%) | called by muse, mutect2
- SCN4B | c.*1998G>T | 3'UTR (SNP) | VAF 60/232 reads (26%) | called by muse, mutect2, varscan2
- TDH | chr8:11347457 C>A | 5'Flank (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- TG | c.7239+29144C>T | Intron (SNP) | VAF 43/352 reads (12%) | called by muse, mutect2, varscan2
